Somatic mutation profile of tumor specimen 0DBZ59 from CCDI case PBBLIA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.1 years (2,975 days).
Specimen 0DBZ59: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d1962737-448b-4f6c-8321-91bb2ae4c9dd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DBZ53 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f033442f-a65b-4dc6-b473-1fd55205bb1a

The open-access MAF lists 19 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 3, Splice Region 1, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL1 | c.1730C>G p.S577* | Nonsense Mutation (SNP) | VAF 153/327 reads (47%) | catalogued as COSV60104299, COSV60105748; called by muse, mutect2, varscan2
- DUSP4 | c.280C>A p.R94S | Missense Mutation (SNP) | VAF 45/246 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); catalogued as rs967738306; called by muse, mutect2, varscan2
- FABP2 | c.286C>T p.R96W | Missense Mutation (SNP) | VAF 271/766 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753335773, COSV56788432; called by muse, mutect2, varscan2
- H1-7 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 81/440 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs957723539, COSV58601775; called by muse, mutect2, varscan2
- KLHL22 | c.130C>T p.R44W | Missense Mutation (SNP) | VAF 213/414 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778466917, COSV61021214; called by muse, mutect2, varscan2
- OR2T3 | c.241G>A p.V81M | Missense Mutation (SNP) | VAF 225/1127 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs1284758963, COSV100613102; called by muse, mutect2, varscan2
- PCDHB13 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 167/853 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.009); catalogued as COSV53396377; called by muse, mutect2, varscan2
- PRKDC | c.1288G>T p.V430L | Missense Mutation (SNP) | VAF 194/478 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.764); catalogued as rs565514103; called by muse, mutect2, varscan2
- RECK | c.2055C>A p.N685K | Missense Mutation (SNP) | VAF 129/672 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.024); catalogued as rs145965365, COSV100937450; called by muse, mutect2, varscan2
- SF3A1 | c.1531C>G p.R511G | Missense Mutation (SNP) | VAF 112/610 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.931); catalogued as COSV53168668; called by muse, mutect2, varscan2
- TIE1 | c.266C>T p.T89M | Missense Mutation (SNP) | VAF 74/303 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.511); catalogued as rs1442012423, COSV65250701; called by muse, mutect2, varscan2
- ANKRD36 | c.3294G>A p.K1098= | Splice Region (SNP) | VAF 70/832 reads (8%) | called by muse, mutect2, varscan2
- MMEL1 | c.1715A>G p.N572S | Missense Mutation (SNP) | VAF 69/700 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2
- PAX3 | c.554A>G p.K185R | Missense Mutation (SNP) | VAF 130/715 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- TP53BP1 | c.3012G>T p.Q1004H | Missense Mutation (SNP) | VAF 139/768 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PCDHGA8 | c.1887G>A p.A629= | Silent (SNP) | VAF 34/173 reads (20%) | catalogued as rs775789970; called by muse, mutect2, varscan2
- SAMD9 | c.3579T>C p.N1193= | Silent (SNP) | VAF 382/1054 reads (36%) | called by muse, mutect2, varscan2
- TRIM51 | c.1290G>T p.L430= | Silent (SNP) | VAF 22/751 reads (3%) | called by muse, mutect2
- FGF3 | c.-11G>T | 5'UTR (SNP) | VAF 41/201 reads (20%) | called by muse, mutect2, varscan2
